Somatic mutation profile of tumor specimen TCGA-CV-7178-01A (aliquot TCGA-CV-7178-01A-21D-2012-08) from TCGA case TCGA-CV-7178, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Overlapping lesion of lip, oral cavity and pharynx; AJCC pathologic stage: Stage IVA; Tumor grade: G3; Age at diagnosis: 64.1 years (23,430 days).
Specimen TCGA-CV-7178-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ff701884-755b-4012-a137-bc8c55d7a73a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CV-7178-10A (Blood Derived Normal), aliquot TCGA-CV-7178-10A-01D-2013-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5611c808-8630-4171-b607-547358430d37

The open-access MAF lists 125 somatic variants for this specimen: 91 protein-altering or splice-affecting, 31 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 79, Silent 31, Nonsense Mutation 7, RNA 2, Splice Region 1, Splice Site 1, Intron 1, Nonstop Mutation 1, In Frame Del 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.801_818del p.N268_R273del | In Frame Del (DEL) | VAF 12/36 reads (33%) | hotspot (GDC flag); called by mutect2, pindel
- ADRA2B | c.1275C>G p.I425M | Missense Mutation (SNP) | VAF 5/37 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV69787476; called by muse, mutect2, varscan2
- AEBP1 | c.3106C>T p.R1036W | Missense Mutation (SNP) | VAF 11/50 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.549); catalogued as rs534996461, COSV99789180; called by muse, mutect2, varscan2
- ANLN | c.1963C>T p.R655* | Nonsense Mutation (SNP) | VAF 23/190 reads (12%) | catalogued as rs1301425931, COSV56073710, COSV99733006; called by muse, mutect2, varscan2
- ANP32E | c.602A>G p.D201G | Missense Mutation (SNP) | VAF 30/95 reads (32%) | SIFT tolerated (0.41); PolyPhen benign (0.035); catalogued as COSV100029796; called by muse, mutect2, varscan2
- AP1M1 | c.437C>T p.A146V | Missense Mutation (SNP) | VAF 27/74 reads (36%) | SIFT tolerated (0.21); PolyPhen benign (0.009); catalogued as rs760488719, COSV52226362; called by muse, mutect2, varscan2
- APAF1 | c.1229A>T p.E410V (on ENST00000551964 / NM_181861.2; = p.E399V on NM_001160.3) | Missense Mutation (SNP) | VAF 20/93 reads (22%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.947); catalogued as COSV100244504; called by muse, mutect2, varscan2
- APLP2 | c.254A>T p.E85V | Missense Mutation (SNP) | VAF 15/39 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99600170; called by muse, mutect2, varscan2
- ASPM | c.7463A>C p.Q2488P | Missense Mutation (SNP) | VAF 15/137 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99661310; called by muse, mutect2, varscan2
- ASTN2 | c.394G>A p.A132T | Missense Mutation (SNP) | VAF 16/51 reads (31%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.042); catalogued as rs780926316, COSV100531027; called by muse, mutect2, varscan2
- ATAD2 | c.3058G>C p.D1020H | Missense Mutation (SNP) | VAF 18/198 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV54885975; called by muse, mutect2
- AUTS2 | c.3715C>G p.P1239A | Missense Mutation (SNP) | VAF 13/50 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100719743; called by muse, mutect2, varscan2
- C8orf76 | c.298G>A p.A100T | Missense Mutation (SNP) | VAF 42/78 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99415275; called by muse, mutect2, varscan2
- CACNA2D4 | c.120G>T p.M40I | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT tolerated, low confidence (0.48); PolyPhen benign (0); catalogued as rs528227884, COSV99766757; called by muse, varscan2
- CDH6 | c.1070G>T p.R357L | Missense Mutation (SNP) | VAF 47/113 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.952); catalogued as rs773989887, COSV54076363, COSV99421172; called by muse, mutect2, varscan2
- CDS2 | c.991C>T p.R331W | Missense Mutation (SNP) | VAF 30/149 reads (20%) | SIFT tolerated (0.22); PolyPhen benign (0.005); catalogued as rs376439839; called by muse, mutect2, varscan2
- CHRNG | c.504C>A p.F168L | Missense Mutation (SNP) | VAF 37/146 reads (25%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.948); catalogued as COSV101264054; called by muse, mutect2, varscan2
- COL9A2 | c.1097C>T p.P366L | Missense Mutation (SNP) | VAF 12/60 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101028826; called by muse, mutect2, varscan2
- CSGALNACT2 | c.280C>T p.R94W | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.865); catalogued as rs368373201; called by muse, mutect2, varscan2
- CTTNBP2 | c.188G>A p.R63Q | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT tolerated (0.13); PolyPhen benign (0.034); catalogued as rs376703729, COSV99355098, COSV99355281; called by muse, varscan2
- DHRS4 | c.836G>C p.*279Sext*13 | Nonstop Mutation (SNP) | VAF 11/42 reads (26%) | catalogued as rs754470555, COSV100366085; called by muse, mutect2, varscan2
- DPYD | c.2240A>T p.D747V | Missense Mutation (SNP) | VAF 24/93 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.898); catalogued as COSV100929620; called by muse, mutect2, varscan2
- DSTYK | c.1840C>T p.R614W | Missense Mutation (SNP) | VAF 28/107 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1300122167, COSV100904756; called by muse, mutect2, varscan2
- EPB41L1 | c.1693G>A p.E565K | Missense Mutation (SNP) | VAF 7/43 reads (16%) | SIFT tolerated (0.13); PolyPhen benign (0.013); catalogued as rs1474353645, COSV99153887; called by muse, varscan2
- EPS8L3 | c.1303C>T p.Q435* | Nonsense Mutation (SNP) | VAF 43/191 reads (23%) | catalogued as rs1209443136, COSV100719769; called by muse, mutect2, varscan2
- ESRRB | c.574G>A p.E192K | Missense Mutation (SNP) | VAF 5/80 reads (6%) | SIFT tolerated (0.13); PolyPhen benign (0.434); catalogued as COSV99835903, COSV99836010; called by muse, mutect2
- F11 | c.805A>T p.I269F | Missense Mutation (SNP) | VAF 15/59 reads (25%) | SIFT tolerated (0.2); PolyPhen benign (0.01); catalogued as COSV99251954; called by muse, mutect2, varscan2
- FEZF1 | c.185A>G p.K62R | Missense Mutation (SNP) | VAF 24/140 reads (17%) | SIFT tolerated (0.07); PolyPhen benign (0.122); catalogued as COSV100484573; called by muse, mutect2, varscan2
- FLRT3 | c.608G>A p.R203H | Missense Mutation (SNP) | VAF 34/103 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs1433795820, COSV54047353; called by muse, mutect2, varscan2
- FLT1 | c.2036C>A p.T679N | Missense Mutation (SNP) | VAF 22/108 reads (20%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.649); catalogued as COSV99169631; called by muse, mutect2, varscan2
- FMN2 | c.4859C>A p.A1620D | Missense Mutation (SNP) | VAF 30/139 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100147726; called by muse, mutect2, varscan2
- FOXD4L1 | c.703C>G p.L235V | Missense Mutation (SNP) | VAF 36/186 reads (19%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.899); catalogued as COSV99380899; called by muse, mutect2, varscan2
- GINM1 | c.226G>C p.D76H | Missense Mutation (SNP) | VAF 16/59 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.891); catalogued as COSV100805387; called by muse, mutect2, varscan2
- GPR158 | c.2613G>T p.E871D | Missense Mutation (SNP) | VAF 29/109 reads (27%) | SIFT tolerated (0.57); PolyPhen benign (0.011); catalogued as COSV100894418; called by muse, mutect2, varscan2
- HAS2 | c.1606A>G p.K536E | Missense Mutation (SNP) | VAF 71/183 reads (39%) | SIFT deleterious (0.02); PolyPhen benign (0.065); catalogued as COSV100392260; called by muse, mutect2, varscan2
- HLA-DRA | c.88C>T p.H30Y | Missense Mutation (SNP) | VAF 53/232 reads (23%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.988); catalogued as COSV100895096; called by muse, mutect2, varscan2
- IL12RB2 | c.2416G>A p.D806N | Missense Mutation (SNP) | VAF 64/251 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0.007); catalogued as COSV99255787; called by muse, mutect2, varscan2
- INHA | c.724T>A p.S242T | Missense Mutation (SNP) | VAF 10/48 reads (21%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.934); catalogued as COSV99217659; called by muse, mutect2, varscan2
- KCNJ5 | c.631C>T p.R211W | Missense Mutation (SNP) | VAF 19/87 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs143790141, CM166035; called by muse, mutect2, varscan2
- KLHDC9 | c.690G>A p.E230= | Splice Region (SNP) | VAF 319/589 reads (54%) | catalogued as COSV100919708; called by muse, mutect2, varscan2
- KLKB1 | c.1489+1G>A p.X497_splice | Splice Site (SNP) | VAF 9/25 reads (36%) | catalogued as COSV99250543; called by muse, mutect2, varscan2
- LARP6 | c.1303A>T p.R435W | Missense Mutation (SNP) | VAF 43/129 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100151137; called by muse, mutect2, varscan2
- LIN28A | c.495G>C p.Q165H | Missense Mutation (SNP) | VAF 9/65 reads (14%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.993); catalogued as rs1305446335, COSV99575510; called by muse, mutect2, varscan2
- LYN | c.1238A>G p.E413G | Missense Mutation (SNP) | VAF 11/103 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV101319647; called by muse, mutect2, varscan2
- MC1R | c.520G>A p.V174I | Missense Mutation (SNP) | VAF 12/78 reads (15%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as rs762183931, CD041917, COSV100206153; called by muse, mutect2, varscan2
- MFSD10 | c.1202G>A p.R401H | Missense Mutation (SNP) | VAF 5/10 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs778286832, COSV99297185; called by muse, varscan2
- MIS18BP1 | c.3029A>T p.D1010V | Missense Mutation (SNP) | VAF 31/95 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.273); catalogued as COSV100173342; called by muse, mutect2, varscan2
- MOG | c.446A>G p.Y149C | Missense Mutation (SNP) | VAF 53/113 reads (47%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV100973175; called by muse, mutect2, varscan2
- MON1B | c.1348G>T p.D450Y | Missense Mutation (SNP) | VAF 8/54 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV99941896; called by muse, mutect2, varscan2
- MUC17 | c.2840C>G p.T947S | Missense Mutation (SNP) | VAF 187/619 reads (30%) | SIFT tolerated (0.31); PolyPhen benign (0.003); catalogued as COSV100073432; called by muse, mutect2, varscan2
- NCAN | c.383G>A p.G128E | Missense Mutation (SNP) | VAF 10/23 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as COSV99388568; called by muse, mutect2, varscan2
- NECTIN4 | c.490G>T p.G164C | Missense Mutation (SNP) | VAF 12/71 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV100919818; called by muse, mutect2, varscan2
- NLGN2 | c.997C>G p.P333A | Missense Mutation (SNP) | VAF 29/69 reads (42%) | SIFT tolerated (0.3); PolyPhen benign (0.365); catalogued as COSV100259660; called by muse, mutect2, varscan2
- NLRP2 | c.1945A>G p.N649D | Missense Mutation (SNP) | VAF 10/55 reads (18%) | SIFT tolerated (0.34); PolyPhen benign (0.021); catalogued as COSV99672723; called by muse, mutect2, varscan2
- NOTCH2 | c.733G>T p.E245* | Nonsense Mutation (SNP) | VAF 8/41 reads (20%) | catalogued as COSV56711599, COSV99867353; called by muse, mutect2, varscan2
- OR4M1 | c.219C>G p.Y73* | Nonsense Mutation (SNP) | VAF 114/484 reads (24%) | catalogued as COSV100271018, COSV100271570; called by muse, mutect2, varscan2
- OR51A4 | c.524A>G p.Q175R | Missense Mutation (SNP) | VAF 51/136 reads (38%) | SIFT deleterious (0.03); PolyPhen benign (0.012); catalogued as COSV100985395; called by muse, mutect2, varscan2
- P2RY2 | c.1030A>G p.T344A | Missense Mutation (SNP) | VAF 18/181 reads (10%) | SIFT tolerated (0.42); PolyPhen benign (0.003); catalogued as COSV100232897; called by muse, mutect2, varscan2
- PKD2L1 | c.2259A>T p.Q753H | Missense Mutation (SNP) | VAF 31/64 reads (48%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.088); catalogued as COSV100559475; called by muse, mutect2, varscan2
- PLCB1 | c.302G>A p.R101H | Missense Mutation (SNP) | VAF 34/114 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.039); catalogued as rs746490695, COSV62058490; called by muse, mutect2, varscan2
- PLCB2 | c.3358C>T p.Q1120* | Nonsense Mutation (SNP) | VAF 5/68 reads (7%) | catalogued as COSV99542769; called by muse, mutect2
- PRPSAP2 | c.399G>C p.M133I | Missense Mutation (SNP) | VAF 22/89 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.85); catalogued as COSV99264781; called by muse, mutect2, varscan2
- PRSS1 | c.344C>G p.S115* | Nonsense Mutation (SNP) | VAF 29/192 reads (15%) | catalogued as COSV100298554; called by muse, varscan2
- PRTG | c.2281C>A p.P761T | Missense Mutation (SNP) | VAF 18/107 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101221522; called by muse, mutect2, varscan2
- RSPH3 | c.1208G>A p.R403H (on ENST00000252655; = p.R261H on NM_031924.8) | Missense Mutation (SNP) | VAF 11/51 reads (22%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.899); catalogued as rs921491169, COSV51921466; called by muse, mutect2, varscan2
- RTL3 | c.1056G>C p.W352C | Missense Mutation (SNP) | VAF 18/60 reads (30%) | SIFT deleterious (0.03); PolyPhen benign (0.005); catalogued as COSV100330179, COSV58185920; called by muse, mutect2, varscan2
- SETX | c.261A>T p.L87F | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV99811252; called by muse, mutect2, varscan2
- SHANK3 | c.1873G>A p.E625K | Missense Mutation (SNP) | VAF 9/57 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs890119395, COSV99438209; called by muse, mutect2, varscan2
- SIPA1L1 | c.4612G>A p.E1538K | Missense Mutation (SNP) | VAF 13/72 reads (18%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.669); catalogued as COSV100666157; called by muse, mutect2, varscan2
- SLC12A1 | c.219C>A p.F73L | Missense Mutation (SNP) | VAF 14/72 reads (19%) | SIFT tolerated (0.66); PolyPhen benign (0.017); catalogued as COSV100372630, COSV57708398; called by muse, mutect2, varscan2
- SLITRK5 | c.125A>T p.D42V | Missense Mutation (SNP) | VAF 24/156 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.071); catalogued as COSV100281324; called by muse, mutect2, varscan2
- SLTM | c.1816C>T p.P606S | Missense Mutation (SNP) | VAF 12/51 reads (24%) | SIFT tolerated (0.38); PolyPhen possibly damaging (0.588); catalogued as COSV99989445; called by muse, mutect2, varscan2
- SNPH | c.425T>A p.I142N | Missense Mutation (SNP) | VAF 35/135 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100378466; called by muse, mutect2, varscan2
- SOX8 | c.520C>T p.R174W | Missense Mutation (SNP) | VAF 11/56 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99559411; called by muse, mutect2, varscan2
- SPANXN2 | c.160G>T p.V54L | Missense Mutation (SNP) | VAF 52/140 reads (37%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.621); catalogued as COSV100980032; called by muse, varscan2
- TAP1 | c.1555G>A p.E519K | Missense Mutation (SNP) | VAF 11/44 reads (25%) | SIFT tolerated (0.08); PolyPhen benign (0.098); catalogued as COSV100841340; called by muse, mutect2, varscan2
- TDRD1 | c.3110G>A p.R1037K | Missense Mutation (SNP) | VAF 13/57 reads (23%) | SIFT tolerated (0.31); PolyPhen probably damaging (0.987); catalogued as COSV99315386; called by muse, mutect2, varscan2
- TNFRSF11B | c.877G>A p.E293K | Missense Mutation (SNP) | VAF 18/133 reads (14%) | SIFT tolerated (0.11); PolyPhen benign (0.385); catalogued as rs765292859, COSV99816785; called by muse, mutect2, varscan2
- TOX3 | c.1012C>G p.Q338E | Missense Mutation (SNP) | VAF 13/74 reads (18%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.93); catalogued as COSV99568275; called by muse, mutect2
- TRAM1L1 | c.1106C>T p.S369L | Missense Mutation (SNP) | VAF 52/118 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.835); catalogued as rs750351492, COSV100162411; called by muse, mutect2, varscan2
- TTN | c.78668C>A p.P26223H (on ENST00000591111; = p.P18799H on NM_003319.4) | Missense Mutation (SNP) | VAF 12/69 reads (17%) | PolyPhen probably damaging (1); catalogued as COSV100634589; called by muse, mutect2, varscan2
- TTN | c.7159G>A p.V2387I (on ENST00000591111; = p.V2341I on NM_003319.4) | Missense Mutation (SNP) | VAF 23/140 reads (16%) | PolyPhen benign (0.003); catalogued as rs377691143, COSV60175301; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- WWOX | c.441T>G p.H147Q | Missense Mutation (SNP) | VAF 18/54 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.393); catalogued as COSV100880658; called by muse, mutect2, varscan2
- ZC3H12C | c.1385G>A p.G462E | Missense Mutation (SNP) | VAF 26/58 reads (45%) | SIFT deleterious (0.04); PolyPhen benign (0.03); catalogued as COSV99585441; called by muse, mutect2, varscan2
- ZNF100 | c.344A>T p.Q115L | Missense Mutation (SNP) | VAF 7/37 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.046); catalogued as COSV99974414; called by muse, mutect2, varscan2
- ZNF184 | c.352G>A p.E118K | Missense Mutation (SNP) | VAF 46/91 reads (51%) | SIFT tolerated (0.29); PolyPhen benign (0.01); catalogued as COSV53006144; called by muse, mutect2, varscan2
- ZNF304 | c.1031A>G p.Y344C | Missense Mutation (SNP) | VAF 18/55 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.707); catalogued as rs1220267257, COSV99988918; called by muse, mutect2, varscan2
- ZNF354A | c.292C>G p.Q98E | Missense Mutation (SNP) | VAF 40/89 reads (45%) | SIFT tolerated (1); PolyPhen probably damaging (0.93); catalogued as COSV100234711; called by muse, mutect2, varscan2
- ZNF621 | c.311C>G p.S104C | Missense Mutation (SNP) | VAF 19/58 reads (33%) | SIFT tolerated (0.08); PolyPhen benign (0.006); catalogued as COSV100182589; called by muse, mutect2, varscan2
- FRMD7 | c.1492dup p.Y498Lfs*15 | Frame Shift Ins (INS) | VAF 28/146 reads (19%) | called by mutect2, varscan2
- TRAC | c.91C>T p.Q31* | Nonsense Mutation (SNP) | VAF 30/206 reads (15%) | called by muse, mutect2, varscan2
- ABCC5 | c.2127C>T p.D709= | Silent (SNP) | VAF 21/143 reads (15%) | catalogued as rs201577338, COSV99657859; called by muse, mutect2, varscan2
- ACP6 | c.327A>G p.Q109= | Silent (SNP) | VAF 13/107 reads (12%) | catalogued as rs1348716223, COSV100984268; called by muse, mutect2, varscan2
- ARHGAP39 | c.2235G>A p.E745= | Silent (SNP) | VAF 34/90 reads (38%) | catalogued as COSV99432446; called by muse, mutect2, varscan2
- ATP2B2 | c.1191G>A p.T397= (on ENST00000352432; = p.T363= on NM_001683.5) | Silent (SNP) | VAF 15/27 reads (56%) | catalogued as rs372813016, COSV100659632; called by muse, mutect2, varscan2
- AUP1 | c.570G>T p.L190= | Silent (SNP) | VAF 19/65 reads (29%) | catalogued as COSV99240022; called by muse, mutect2, varscan2
- CAD | c.3627G>A p.Q1209= | Silent (SNP) | VAF 39/211 reads (18%) | catalogued as rs1408520981, COSV99256019; called by muse, mutect2, varscan2
- CDH17 | c.984A>G p.V328= | Silent (SNP) | VAF 21/119 reads (18%) | catalogued as COSV99218188; called by muse, mutect2, varscan2
- CNTN2 | c.1710G>A p.G570= | Silent (SNP) | VAF 9/86 reads (10%) | catalogued as COSV100085602; called by muse, mutect2, varscan2
- CYB5D2 | c.351C>T p.H117= | Silent (SNP) | VAF 33/69 reads (48%) | catalogued as rs1382170677, COSV100029068; called by muse, mutect2, varscan2
- DISP1 | c.3222C>T p.F1074= | Silent (SNP) | VAF 24/103 reads (23%) | catalogued as COSV99452408; called by muse, mutect2, varscan2
- DNA2 | c.486C>T p.L162= | Silent (SNP) | VAF 7/32 reads (22%) | catalogued as rs747798578, COSV100622896; called by muse, mutect2, varscan2
- EIF2AK4 | c.1989G>A p.A663= | Silent (SNP) | VAF 9/40 reads (23%) | catalogued as COSV99774636, COSV99775533; called by muse, mutect2, varscan2
- FBXO10 | c.2008C>T p.L670= | Silent (SNP) | VAF 16/36 reads (44%) | catalogued as COSV99447397; called by muse, mutect2, varscan2
- ISLR | c.417C>T p.R139= | Silent (SNP) | VAF 20/89 reads (22%) | catalogued as rs759129192, COSV51432972; called by muse, mutect2, varscan2
- KCND2 | c.1647T>C p.H549= | Silent (SNP) | VAF 16/124 reads (13%) | catalogued as COSV100479190; called by muse, mutect2, varscan2
- KIF21B | c.4629G>A p.A1543= (on ENST00000422435 / NM_001252100.2; = p.A1530= on NM_017596.4) | Silent (SNP) | VAF 17/152 reads (11%) | catalogued as rs140999969; called by muse, mutect2, varscan2
- LRRK2 | c.1245C>T p.F415= | Silent (SNP) | VAF 14/44 reads (32%) | catalogued as COSV100111393; called by muse, mutect2, varscan2
- MYO10 | c.4071G>A p.T1357= | Silent (SNP) | VAF 29/238 reads (12%) | catalogued as COSV99946554; called by muse, mutect2, varscan2
- NRIP3 | c.393C>T p.L131= | Silent (SNP) | VAF 20/104 reads (19%) | catalogued as rs770549056, COSV100487285; called by muse, mutect2, varscan2
- OR10J1 | c.510T>C p.A170= | Silent (SNP) | VAF 66/226 reads (29%) | catalogued as COSV101420064; called by muse, mutect2, varscan2
- SPRED2 | c.873G>A p.Q291= | Silent (SNP) | VAF 21/126 reads (17%) | catalogued as COSV100710383; called by muse, mutect2, varscan2
- TNFSF9 | c.279G>A p.A93= | Silent (SNP) | VAF 61/141 reads (43%) | catalogued as rs1396996641, COSV99832390; called by muse, mutect2, varscan2
- TOX3 | c.1011C>A p.A337= | Silent (SNP) | VAF 13/75 reads (17%) | catalogued as COSV99568279; called by muse, mutect2
- TRIB3 | c.16C>T p.L6= | Silent (SNP) | VAF 20/106 reads (19%) | catalogued as COSV99424062; called by muse, mutect2, varscan2
- TRMT112 | c.123C>T p.F41= | Silent (SNP) | VAF 42/94 reads (45%) | catalogued as COSV99135029; called by muse, mutect2, varscan2
- UVSSA | c.2064C>T p.A688= | Silent (SNP) | VAF 52/102 reads (51%) | catalogued as rs369372040; called by muse, mutect2, varscan2
- WNT3A | c.276C>T p.H92= | Silent (SNP) | VAF 14/98 reads (14%) | catalogued as rs201572822; called by muse, mutect2, varscan2
- ZBTB43 | c.288C>T p.P96= | Silent (SNP) | VAF 19/66 reads (29%) | catalogued as rs770929392, COSV100991335, COSV100991491; called by muse, mutect2, varscan2
- ZMIZ2 | c.795C>G p.V265= | Silent (SNP) | VAF 15/98 reads (15%) | catalogued as COSV99537311; called by muse, mutect2, varscan2
- ZNF644 | c.2985C>T p.A995= | Silent (SNP) | VAF 17/78 reads (22%) | catalogued as COSV100494793; called by muse, mutect2, varscan2
- ZNF644 | c.1305G>A p.G435= | Silent (SNP) | VAF 20/79 reads (25%) | catalogued as COSV100494796; called by muse, mutect2, varscan2
- DNM1P46 | n.832G>T | RNA (SNP) | VAF 6/24 reads (25%) | catalogued as rs755239712; called by muse, mutect2, varscan2
- NACA | c.70+3790C>G | Intron (SNP) | VAF 9/54 reads (17%) | catalogued as COSV63271542; called by muse, mutect2, varscan2
- SPATA8 | n.761C>T | RNA (SNP) | VAF 18/129 reads (14%) | catalogued as rs761933735, COSV60704103; called by muse, mutect2, varscan2
